Somatic mutation profile of tumor specimen 878c2524-208e-40b2-8089-ceb820 (aliquot 878c2524-208e-40b2-8089-ceb820_D6) from CPTAC case 13BR009, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.9 years (27,374 days).
Specimen 878c2524-208e-40b2-8089-ceb820: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 669189bc-0fa1-45b2-9fb3-8874faf10695.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d6aff277-c3bf-4977-bb41-64debf (Blood Derived Normal), aliquot d6aff277-c3bf-4977-bb41-64debf_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c9ceba0-c994-45b4-9f3d-b6c3aec695d1

The open-access MAF lists 102 somatic variants for this specimen: 62 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 25, Intron 9, 3'UTR 4, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL1 | c.1279C>T p.H427Y | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs749462151; called by muse, mutect2, varscan2
- AIG1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV51636026; called by muse, varscan2
- CCDC42 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs201999758, COSV99549791; called by muse, mutect2, varscan2
- CD248 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs774123813; called by muse, mutect2, varscan2
- CXADR | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV53030118; called by muse, varscan2
- EPS8L2 | c.1708A>C p.S570R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as rs1233495582; called by muse, mutect2
- GUCY1A2 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 45/102 reads (44%) | catalogued as rs529839329, COSV56477145; called by muse, mutect2, varscan2
- H2BC17 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58152542; called by muse, mutect2, varscan2
- KCNMB1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as rs369035536; called by muse, mutect2, varscan2
- NDUFV1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs374003063, COSV59594890; called by mutect2, varscan2
- NOBOX | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV56195118; called by muse, mutect2, varscan2
- NT5C1A | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs371614500; called by muse, mutect2, varscan2
- PCDHA13 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 194/1014 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56493541; called by muse, varscan2
- PLCD3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1200174880; called by muse, mutect2, varscan2
- POMGNT1 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 74/243 reads (30%) | PolyPhen probably damaging (1); catalogued as rs886044567, COSV64341031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4G | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775552640; called by muse, mutect2, varscan2
- SLC25A19 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57468726; called by muse, mutect2, varscan2
- TRIM42 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV53885989; called by muse, mutect2, varscan2
- VWA7 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV63305222; called by muse, mutect2, varscan2
- ZNF469 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 126/436 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558293585; called by muse, mutect2, varscan2
- ACTRT2 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADAMTS9 | c.1654G>C p.G552R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ADGRG2 | c.2561G>A p.G854E (on ENST00000379869 / NM_001079858.3; = p.G851E on NM_005756.4) | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF2 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 20/736 reads (3%) | called by muse, mutect2
- ARHGEF10 | c.1247C>T p.S416F (on ENST00000398564; = p.S391F on NM_014629.4) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CATSPERB | c.2312A>G p.N771S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- CCT6A | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by mutect2, varscan2
- CEP350 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, varscan2
- CEP350 | c.3426G>C p.K1142N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2
- CLCA1 | c.2152_2154del p.K718del | In Frame Del (DEL) | VAF 22/110 reads (20%) | called by mutect2, pindel, varscan2
- CMYA5 | c.10871dup p.M3625Dfs*26 | Frame Shift Ins (INS) | VAF 31/105 reads (30%) | called by pindel, varscan2
- CXADR | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- CXADR | c.834-20_862del p.X278_splice | Splice Site (DEL) | VAF 22/188 reads (12%) | called by mutect2, pindel
- DCP1B | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ERCC6 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- GCFC2 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GLUD2 | c.972del p.A325Lfs*55 | Frame Shift Del (DEL) | VAF 87/528 reads (16%) | called by mutect2, varscan2
- GTF3C1 | c.4557C>G p.I1519M | Missense Mutation (SNP) | VAF 75/507 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- HERC2 | c.8285G>T p.R2762L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IGSF10 | c.1422G>C p.M474I | Missense Mutation (SNP) | VAF 37/418 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2
- ITGA4 | c.1538T>C p.I513T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- KIAA1958 | c.766G>T p.V256F | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LAMB2 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC9 | c.1034dup p.N345Kfs*5 | Frame Shift Ins (INS) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- NBPF15 | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 115/237 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- NOL6 | c.1207-2dup p.X403_splice | Splice Site (INS) | VAF 64/195 reads (33%) | called by mutect2, pindel, varscan2
- OIT3 | c.1221_1224delinsT p.P408del | In Frame Del (DEL) | VAF 34/152 reads (22%) | called by pindel, varscan2*
- OR13C3 | c.864G>T p.M288I | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2
- PDE1C | c.2065A>T p.M689L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM3 | c.1823_1839del p.A608Gfs*2 | Frame Shift Del (DEL) | VAF 94/235 reads (40%) | called by mutect2, pindel, varscan2
- SLC18A2 | c.991+1G>A p.X331_splice | Splice Site (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- TIAM1 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2
- TNRC6A | c.5212A>T p.T1738S | Missense Mutation (SNP) | VAF 24/861 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- TRAF3IP3 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.043); called by muse, mutect2
- TRIM45 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, varscan2
- TTR | c.336+3G>A | Splice Region (SNP) | VAF 80/485 reads (16%) | called by muse, mutect2, varscan2
- USP38 | c.1688A>T p.Q563L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- UXT | c.192C>A p.H64Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWC2 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- XRCC1 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF593 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF728 | c.486A>C p.R162S | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AATK | c.774C>T p.N258= (on ENST00000326724 / NM_001080395.3; = p.N155= on NM_004920.2) | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- C21orf62 | c.438G>A p.G146= | Silent (SNP) | VAF 51/227 reads (22%) | catalogued as COSV101212302; called by muse, mutect2, varscan2
- CCDC141 | c.1065G>A p.A355= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs756215131; called by muse, mutect2, varscan2
- CDH26 | c.1230C>T p.V410= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- EVI5L | c.390C>T p.S130= | Silent (SNP) | VAF 70/377 reads (19%) | catalogued as rs1267629224; called by muse, mutect2, varscan2
- FLG | c.1527C>A p.S509= | Silent (SNP) | VAF 118/856 reads (14%) | called by mutect2, varscan2
- GBA3 | c.162C>A p.G54= | Silent (SNP) | VAF 117/242 reads (48%) | called by muse, mutect2, varscan2
- GLCE | c.1269A>C p.P423= | Silent (SNP) | VAF 78/231 reads (34%) | called by muse, mutect2, varscan2
- ICMT | c.375C>A p.L125= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV59473514; called by muse, mutect2
- JCAD | c.127C>T p.L43= | Silent (SNP) | VAF 56/213 reads (26%) | catalogued as rs1422618585; called by muse, mutect2, varscan2
- NCOR2 | c.1203C>T p.D401= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs1253471994; called by muse, mutect2, varscan2
- OBSCN | c.12000C>T p.C4000= | Silent (SNP) | VAF 29/618 reads (5%) | catalogued as rs374501640; called by muse, mutect2
- OR2L8 | c.291G>C p.G97= | Silent (SNP) | VAF 138/427 reads (32%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2025G>A p.A675= | Silent (SNP) | VAF 63/1002 reads (6%) | catalogued as rs782515896, COSV100969107; called by muse, mutect2
- PCDHGA11 | c.2073G>A p.S691= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1293301567, COSV99537359; called by muse, mutect2, varscan2
- PLXNC1 | c.315C>T p.F105= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- PP2D1 | c.120G>A p.K40= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- PRLHR | c.223C>T p.L75= | Silent (SNP) | VAF 140/368 reads (38%) | called by muse, mutect2, varscan2
- RANBP3L | c.840A>G p.R280= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- RIMS2 | c.1542T>C p.S514= (on ENST00000666250 / NM_001348490.2; = p.S322= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- RP1L1 | c.1380C>T p.G460= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- SEMA6B | c.1956C>T p.S652= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TNIK | c.1047G>A p.T349= | Silent (SNP) | VAF 84/438 reads (19%) | catalogued as rs200227421; called by muse, mutect2, varscan2
- TRIM45 | c.354G>A p.V118= | Silent (SNP) | VAF 42/380 reads (11%) | called by muse, varscan2
- ZBTB45 | c.273G>A p.S91= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as rs770668950; called by muse, mutect2, varscan2
- AC004522.2 | n.57C>T | RNA (SNP) | VAF 6/40 reads (15%) | catalogued as rs1436136608; called by mutect2, varscan2
- ACP2 | c.297+47T>C | Intron (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- ADH1C | c.*13G>A | 3'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs549453609; called by muse, mutect2, varscan2
- CYTH2 | c.808+1105G>T | Intron (SNP) | VAF 44/78 reads (56%) | catalogued as rs775320613; called by muse, mutect2, varscan2
- DUSP13 | c.*416G>A | 3'UTR (SNP) | VAF 21/87 reads (24%) | catalogued as rs779573065, COSV100403299; called by muse, mutect2, varscan2
- KLHL7 | c.*200A>C | 3'UTR (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- LEPR | c.2674-3035C>T | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs762314477, COSV62750563; called by muse, mutect2
- LINC00173 | n.963C>T | RNA (SNP) | VAF 16/286 reads (6%) | catalogued as rs1566018228; called by muse, mutect2
- MUCL3 | c.947-814C>T | Intron (SNP) | VAF 7/46 reads (15%) | catalogued as rs779375082; called by muse, mutect2, varscan2
- PIK3CD | c.1471-155C>A | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- PPFIA1 | c.931-18C>G | Intron (SNP) | VAF 96/174 reads (55%) | catalogued as rs750461085; called by muse, varscan2
- SF1 | c.236+56G>A | Intron (SNP) | VAF 7/35 reads (20%) | catalogued as rs542600264; called by muse, mutect2, varscan2
- TTF2 | c.3270-10C>T | Intron (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- XIAP | c.*5986G>C | 3'UTR (SNP) | VAF 12/126 reads (10%) | called by muse, varscan2
- XRCC4 | c.894-42303C>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs749221259; called by mutect2, varscan2
